Surgical pathology report (de-identified scan), TCGA case TCGA-06-0154, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0154-01A (Primary Tumor).

[page 1 of 2]
06-0154

PATHOLOGICAL DIAGNOSIS:

BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSIES: GLIOBLASTOMA MULTIFORME.

ADDENDUM DIAGNOSIS: BRAIN, SITE NOT SPECIFIED, EXCISIONAL BIOPSIES:
GLIOBLASTOMA MULTIFORME.

SPECIAL STAIN REPORT: MIB-1 LABELING INDEX 11%.

Operation/Specimen: Brain, right frontal.

Clinical History and Pre-Op Dx: [REDACTED] with right frontal
enhancing lesion.

GROSS PATHOLOGY: Received fresh, 5 fragments, 0.9 x 0.7 x 0.3 cm in
aggregate, semifirm, tanish brown and hemorrhagic. In total, 1.

INTRAOPERATIVE CONSULTATION, FROZEN SECTION DIAGNOSIS [REDACTED]
Brain, right frontal: Malignant glioma. [REDACTED]

MICROSCOPIC: Portions of a glial neoplastic proliferation, very
cellular, with spindle nuclei with anaplastic features. There is
extensive necrosis and thrombosis of microvessels.

ADDENDUM REPORT

ADDENDUM GROSS DESCRIPTION:

SPECIMEN: Brain tumor.
FIXATIVE: Formalin.
GENERAL: Seven soft, gray-white tissue fragments, 0.2 cm. maximum
dimension to 1.7 x 1.5 x 1 cm.
MAIN FINDINGS: Sectioning reveals areas of hemorrhage and ill-defined,
yellow areas.
SECTIONS: X1-X3, all submitted.

MICROSCOPIC: Portions of cerebrum with a neoplastic proliferation of
glial cells with nuclear features of anaplasia, frequent mitotic

Cont'd.....

[page 2 of 2]
[REDACTED]

figures, microvascular cellular proliferation and areas of necrosis with pseudopalisading. The bulk of the tumor is growing in the white matter, but is also infiltrating the cerebral cortex.

ADDENDUM REPORT:

Immunoperoxidase method for MIB-1 was performed on block X3.

A MIB-1 labeling index of 11% was obtained in the more cellular areas of the tumor.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file b6578714-98af-47e6-a45c-cef5f6180cfc (TCGA-06-0154.A01C82DB-37C0-42DC-B926-840F8B0E64AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).